Surgical pathology report (de-identified scan), TCGA case TCGA-66-2754, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2754-01A (Primary Tumor).

[page 1 of 2]
Examination report

Macroscopic findings:

1. (a-g) Right superior pulmonary lobe: resected lobe tissue weighing 300g and measuring 160 x 150 x 35 mm, with significant mesh-like anthracosis and saggy and limp pulmonary tissue with sclerosis of the frame and marginal, accentuated bullous hyperinflation. In the subpleural area of S 2 there is grayish-white, dense tumor infiltration with anthracotic pigment, measuring 45mm, well demarcated, with omphaloid pleural retraction and unremarkable segmental bronchi B 1 ? 3 without tumor damage. At the hilum there is lump of confluent lymph node metastases, measuring approx. 50mm, and growing exophytically, with a grayish-white, brittle and necrotic surface and anthracotic pigment throughout, mucous membrane extending from B 3 to the central sections is unremarkable. Apart from this, no further remarkable focal findings on laminated sections.
2. L 11: No visible biopsy material.
3. L 10: No visible biopsy material.
4. L 7: Bipartite, blackish, pigmented lymph node tissue, measuring 13 mm together.
5. (a-b) L 4: Segmented lymph-adipose tissue, measuring 30 mm together.
6. (a-c) L 3: Segmented lymph-adipose tissue, measuring 40 mm together, with suspected tumorous, inflamed, indurated nodes and anthracosis. Complete embedment.

Microscopic findings:

1. (HE, b, c and g: EvG) The bronchial resection margin in the instantaneous section and the subsequent paraffin embedment are completely tumor-free as is the adjacent, partially hemorrhagic, adipose connective tissue. The described tumor, composed of immature, partly fusocellular/ sarcomatoid, and partly small and solidly grouped cell structures, with a significantly misaligned nucleoplasmic ratio, frequent mitosis, coarsening of the chromatin and elucidation of the core with partly prominent nucleoli and a narrow cytoplasmic border. No keratinizing growth. Necrosis included. Concomitant stroma desmoplasia. The adjacent tumorous visceral pleura has perifocal, slight fibrous thickening and is retracted. The elastic basal membrane is focally penetrated by the tumor. In the centre of the tumor there is individual, obliterative, vascular tumorous thrombi. B 3 is surrounded by the tumor and focally infiltrated up to the intact mucous membrane. Significant hilar necrosis, including lymph node metastasis conglomeration with sparse, localized lymphatic tissue containing anthracotic pigment. In S1 there is sclerosis and rarefaction of the lung frame with subpleural, bullous hyperinflation and bronchial ectasia.
2. (HE) No tissue material.
3. (HE) As 2.
4. (HE) Tumor-free lymph node tissue with significant anthracosis and sinus histiocytosis.
5. (HE) Further lymph node fragments with anthracotic pigment. In between, metastasis of the carcinoma described above.
6. (HE) Extensive further metastatic tissue with necrotic decay and only very sparse, localized, lymphatic tissue in between.

[page 2 of 2]
Diagnosis: Resected right superior pulmonary lobe with a 45 mm, necrotic, badly differentiated and non-keratinizing squamous cell carcinoma with pleural infiltration, hemangioinvasion, hilar confluent lymph node metastasis conglomerates and tumor-free, bronchial resection margin. Tumor-free pulmonary tissue with significant anthracosis, structural sclerosis and accentuated subplural, emphysematous structure.

2. and 3. No tissue material

4. Tumor-free lymph node tissue from L 7 indicated.

5. and 6. Metastatic lymph nodes at the sections indicated - L 4 and L 3.

Assessment:

On account of the histological form of a squamous cell carcinoma, it is hard to establish definitely whether this is metastasis of a clinically-indicated squamous cell carcinoma of the oesophagus or a primary pulmonary squamous cell carcinoma. In the case of the latter assumption the tumor stage would be as follows M:8070/3, G 3, PT 2, PV 1, PN 2, PMX, stage III A.

Source: NCI Genomic Data Commons file 69083c2e-4451-4c9a-ad08-3c3b7d280fac (TCGA-66-2754.D291F110-97B0-4EF7-B9EF-552E445E8378.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).